Somatic mutation profile of tumor specimen TARGET-30-PALZRG-01A (aliquot TARGET-30-PALZRG-01A-01W) from TARGET case TARGET-30-PALZRG, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Posterior mediastinum; Age at diagnosis: 1.6 years (577 days).
Specimen TARGET-30-PALZRG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac86377e-f283-4641-94f5-97896c5c466e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALZRG-10A (Blood Derived Normal), aliquot TARGET-30-PALZRG-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60bdaa3a-f90e-4a8e-8e93-a6867be86cb9

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 7, Nonsense Mutation 3, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM6A | c.3904C>T p.Q1302* | Nonsense Mutation (SNP) | VAF 59/156 reads (38%) | catalogued as rs1556375815, COSV65042157; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.7735del p.I2579* | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | catalogued as COSV71288654; called by mutect2, varscan2
- ANAPC2 | c.1692G>C p.M564I | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV60570672; called by muse, mutect2, varscan2
- C5AR2 | c.216G>T p.W72C | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57256520; called by muse, mutect2, varscan2
- FAM221A | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 158/552 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61388055; called by muse, mutect2, varscan2
- IGF2BP1 | c.963C>A p.Y321* | Nonsense Mutation (SNP) | VAF 89/469 reads (19%) | catalogued as COSV51732754; called by muse, mutect2, varscan2
- IRF5 | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.042); catalogued as COSV50858839; called by muse, mutect2, varscan2
- LELP1 | c.228G>T p.K76N | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.76); catalogued as COSV64202527; called by muse, mutect2, varscan2
- MYH8 | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 68/910 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1309092986; called by muse, mutect2
- OSBPL3 | c.489C>A p.F163L | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV57658191; called by muse, mutect2, varscan2
- PGLYRP2 | c.1609G>T p.D537Y | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV52998247; called by muse, mutect2, varscan2
- TTN | c.38732C>G p.S12911W (on ENST00000591111; = p.S5487W on NM_003319.4) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | PolyPhen probably damaging (0.94); catalogued as COSV59958416, COSV60150059; called by muse, mutect2
- ZNF548 | c.439C>A p.H147N | Missense Mutation (SNP) | VAF 117/342 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV60241254; called by muse, mutect2, varscan2
- ZP4 | c.464C>A p.A155E | Missense Mutation (SNP) | VAF 93/386 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV63910757, COSV63912483; called by muse, mutect2, varscan2
- ACACA | c.2980G>T p.E994* | Nonsense Mutation (SNP) | VAF 109/512 reads (21%) | called by muse, mutect2, varscan2
- ITPR1 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- LPIN1 | c.1392del p.I464Mfs*44 | Frame Shift Del (DEL) | VAF 1421/1931 reads (74%) | called by mutect2, pindel, varscan2
- OR10H3 | c.553C>G p.L185V | Missense Mutation (SNP) | VAF 41/901 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.841); called by muse, mutect2
- PGLYRP3 | c.524G>T p.R175M | Missense Mutation (SNP) | VAF 80/668 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- KIF21A | c.3831A>T p.P1277= (on ENST00000361418 / NM_001378440.1; = p.P1264= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/198 reads (18%) | catalogued as COSV62773557; called by muse, mutect2, varscan2
- KRT3 | c.1554G>T p.P518= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV58816078; called by muse, mutect2, varscan2
- MTA3 | c.1098C>G p.T366= | Silent (SNP) | VAF 97/366 reads (27%) | catalogued as rs780840030, COSV68135118; called by muse, mutect2, varscan2
- NPTX2 | c.546C>T p.D182= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs371517261; called by muse, mutect2, varscan2
- ROS1 | c.3915C>A p.I1305= | Silent (SNP) | VAF 70/305 reads (23%) | catalogued as COSV63851064, COSV63856868; called by muse, mutect2, varscan2
- SIRT6 | c.180C>A p.G60= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- TTF2 | c.258A>G p.K86= | Silent (SNP) | VAF 7/127 reads (6%) | called by muse, mutect2
- AP001042.1 | n.2473T>G | RNA (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
